MMRF case MMRF_2781 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ff66e3ae-215c-488e-b54d-d9f5b10038aa

Demographics
Sex at birth: female; Age at index: 65 years; Vital status: Dead; Days to death: 208 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.8 years (24,042 days); ISS stage: II; Days to last known disease status: 208 days; Days to last follow up: 208 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -5, day 208.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Calcium 2.45 mmol/L.
- Albumin 43 g/L.
- Absolute Neutrophil 10.2 ×10⁹/L.
- Lactate Dehydrogenase 6.6 µkat/L.
- Serum Free Immunoglobulin Light Chain, Kappa 142 mg/dL.
- Creatinine 103 µmol/L.
- Hemoglobin 5.27 mmol/L.
- Serum Free Immunoglobulin Light Chain, Lambda 0.19 mg/dL.
- Beta 2 Microglobulin 5.3 µg/mL.
- M Protein 3.77 g/dL.
- Platelets 75 ×10⁹/L.

Other clinical attributes
- Day -5: Weight: 63 kg; Height: 165 cm.

Biospecimens (2 samples)
- Sample MMRF_2781_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_2781_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
